Somatic mutation profile of tumor specimen TCGA-78-7540-01A (aliquot TCGA-78-7540-01A-11D-2063-08) from TCGA case TCGA-78-7540, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Bronchio-alveolar carcinoma, mucinous; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 66.9 years (24,440 days).
Specimen TCGA-78-7540-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52aa22b0-0b50-4fd8-8723-2bfcf445fed9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-78-7540-11A (Solid Tissue Normal), aliquot TCGA-78-7540-11A-01D-2063-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f448407-401e-48d2-b31e-60e70e7c0889

The open-access MAF lists 31 somatic variants for this specimen: 22 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 20, Silent 9, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 8/45 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs121913495, CM158823, COSV55670349, COSV55671845; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 14/24 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by mutect2, varscan2
- ADAMTS7 | c.2255G>T p.G752V | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV66309490; called by muse, mutect2, varscan2
- AKAP9 | c.5035C>T p.R1679C | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs200044616; called by muse, mutect2, varscan2
- ASB2 | c.1265A>G p.Y422C | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV60114505; called by muse, mutect2, varscan2
- ASTN2 | c.673G>A p.V225M | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated, low confidence (0.79); PolyPhen possibly damaging (0.537); catalogued as rs144385545, COSV57754351; called by muse, mutect2, varscan2
- CHIA | c.821G>A p.S274N (on ENST00000343320; = p.S166N on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.367); catalogued as COSV58478341; called by muse, mutect2, varscan2
- COL7A1 | c.3458G>A p.R1153H | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756703259, COSV60403272; called by muse, mutect2, varscan2
- GPR19 | c.1016G>T p.R339I | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60124724; called by muse, mutect2, varscan2
- HYAL2 | c.321G>A p.W107* | Nonsense Mutation (SNP) | VAF 18/56 reads (32%) | catalogued as COSV51701747; called by muse, varscan2
- IGF2BP3 | c.1705C>A p.L569M | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.215); catalogued as COSV51693595; called by muse, mutect2, varscan2
- IL13RA2 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54564596, COSV54567645; called by muse, varscan2
- MAGED2 | c.581G>A p.S194N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.914); catalogued as rs1402748229, COSV54499405; called by muse, varscan2
- OR13C4 | c.46G>C p.G16R | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV52928568; called by muse, mutect2, varscan2
- OTUD6A | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as rs201418224, COSV57974402; called by mutect2, varscan2
- PTPRN2 | c.2495A>T p.Q832L | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67060311; called by muse, mutect2, varscan2
- RUSC2 | c.4474G>A p.D1492N | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.26); catalogued as rs532923022, COSV63430470; called by muse, mutect2, varscan2
- SHC3 | c.791C>T p.T264I | Missense Mutation (SNP) | VAF 55/200 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV65440844; called by muse, mutect2, varscan2
- TLR4 | c.2238G>T p.W746C (on ENST00000355622 / NM_138554.5; = p.W706C on NM_003266.4) | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62924260; called by muse, mutect2, varscan2
- CTSH | c.99T>A p.F33L | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.83); PolyPhen benign (0); called by mutect2, varscan2
- ZFP36L2 | c.111dup p.T38Dfs*46 | Frame Shift Ins (INS) | VAF 7/17 reads (41%) | called by mutect2, varscan2
- GALNT15 | c.667C>T p.L223= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV60219887; called by muse, mutect2, varscan2
- L3MBTL4 | c.504C>T p.A168= | Silent (SNP) | VAF 31/154 reads (20%) | catalogued as COSV53138408, COSV53140916; called by muse, mutect2, varscan2
- LRRC8D | c.1164C>T p.F388= | Silent (SNP) | VAF 22/125 reads (18%) | catalogued as COSV61581285; called by muse, mutect2, varscan2
- MICALL2 | c.2046G>A p.P682= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as rs372015337; called by mutect2, varscan2
- PRAMEF18 | c.216G>A p.T72= | Silent (SNP) | VAF 43/286 reads (15%) | catalogued as rs1273965965; called by muse, mutect2, varscan2
- SLC6A5 | c.1749C>T p.I583= | Silent (SNP) | VAF 23/137 reads (17%) | catalogued as rs372092287, COSV54232608; called by muse, mutect2, varscan2
- SORCS1 | c.2433G>A p.A811= | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as rs758448659, COSV53906163; called by muse, mutect2, varscan2
- STRA6 | c.1047G>A p.Q349= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV60588659; called by muse, mutect2, varscan2
- TSHR | c.1515C>T p.S505= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs774078708, CM961395, COSV53329520, COSV53331945; called by muse, mutect2, varscan2
